Gene-level copy-number profile of tumor specimen TCGA-CF-A8HX-01A from TCGA case TCGA-CF-A8HX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 55.5 years (20,259 days).
Specimen TCGA-CF-A8HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.adad3126-1e34-4f7f-a3cb-e282751d7b0e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CF-A8HX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2808283-4576-4e8c-a5b2-f251cf2c668c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 6,760; copy number 2: 48,131; copy number 3: 4,836; copy number 4: 17; copy number 6: 2; copy number 8: 1; copy number 11: 3; copy number 13: 1; copy number 16: 6; copy number 19: 2; copy number 20: 3; copy number 30: 20; copy number 41: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CF-A8HX-01A-11D-A363-01): tumor purity 0.95, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,438,700, 21 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:73,052,362–73,337,771, 6 genes, copy number 13–20: COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1.
- chr4:73,571,550–73,944,324, 10 genes, copy number 8–16: RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1.
- chr5:130,386,621–130,529,889, 2 genes, copy number 6: RNU7-53P, ARL2BPP4.
- chr11:69,414,307–70,189,528, 20 genes, copy number 30 (within-gene range 2–30): AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1.
- chr11:106,241,974–107,457,844, 11 genes, copy number 41 (within-gene range 1–41): AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1.

Autosomal genes at a single copy (total copy number 1): 5,136. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
